CCDI case PBBRKT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/7a4794f2-75cf-40bc-867d-82d80efa2d94

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Mixed germ cell tumor: ICD-O-3 morphology code: 9085/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.5 years (6,391 days).

Biospecimens (3 samples)
- Sample 0DFMHJ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFMHK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DFMHM: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
